Somatic mutation profile of tumor specimen MP2PRT-PAUKRB-TBP1-A (aliquot MP2PRT-PAUKRB-TBP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUKRB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (715 days).
Specimen MP2PRT-PAUKRB-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f8332c3-113e-4fd8-9633-51d1e5df8eb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUKRB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUKRB-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e39a37cb-ffe8-4240-a828-657b258f849b

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 62/287 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 38/282 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CRTAC1 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 78/352 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as rs750669625; called by muse, mutect2, varscan2
- FTHL17 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 105/412 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs748357093, COSV63266985; called by muse, mutect2, varscan2
- SLITRK3 | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- COBL | c.474C>T p.V158= | Silent (SNP) | VAF 57/278 reads (21%) | catalogued as rs148212268; called by muse, mutect2, varscan2
- DYNC1H1 | c.13162C>T p.L4388= | Silent (SNP) | VAF 65/573 reads (11%) | called by muse, mutect2, varscan2
